TCGA case TCGA-2J-AAB1 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Pancreas; Tissue source site: Mayo Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/75119d1a-93e5-4ae7-9d60-69ee929a0772

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Dead; Days to death: 66 days; Cause of death: Cancer Related; Cause of death source: Medical Record.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 65.6 years (23,962 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Pancreas Head; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 7; Lymph nodes tested: 22; Tumor largest dimension diameter: 4.5 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 38 days; Days to treatment end: 59 days.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 66 days; Disease response: Tumor Free.

Exposures
- Alcohol history: Yes; Alcohol intensity: Drinker; Alcohol drinks per day: 1; Alcohol days per week: 3.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 25; Tobacco smoking onset year: 1962; Tobacco smoking quit year: 1988.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2J-AAB1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-2J-AAB1-01A-01-TS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 40; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-2J-AAB1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2J-AAB1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma-Other Subtype; Histologic diagnosis other: invasive adenocarcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Tumor status: Tumor free; Cause of death: Pancreatic Cancer; Tobacco smoking history indicator: 3; Alcohol exposure intensity: Weekly Drinker; Alcohol consumption frequency: 3; Diabetes diagnosis indicator: No; History chronic pancreatitis: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- New tumor event: New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 66 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 66 days; disease-free interval: no event (censored), 66 days; progression-free interval: no event (censored), 66 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2J-AAB1-01A-11D-A40V-01): tumor purity 0.4, ploidy 1.93, whole-genome doublings 0.
